Somatic mutation profile of tumor specimen TCGA-HT-7620-01A (aliquot TCGA-HT-7620-01A-11D-2253-08) from TCGA case TCGA-HT-7620, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 40.1 years (14,659 days).
Specimen TCGA-HT-7620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffed9650-9c45-40ef-bec1-d68ba8f0d7a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7620-10A (Blood Derived Normal), aliquot TCGA-HT-7620-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d50b083-c8fd-415d-b5e8-d9abe3d01ba6

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 9/40 reads (23%) | hotspot (GDC flag); called by pindel, varscan2
- ANKRD30A | c.403G>A p.V135I (on ENST00000611781; = p.V79I on NM_052997.2) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.939); catalogued as rs761357009, COSV64602855; called by muse, mutect2, varscan2
- CCT7 | c.1269C>G p.Y423* | Nonsense Mutation (SNP) | VAF 28/121 reads (23%) | catalogued as COSV54582970; called by muse, mutect2, varscan2
- CFH | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761751508, COSV62776815; called by muse, mutect2, varscan2
- CLIC2 | c.449T>G p.L150* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as COSV58935915; called by muse, mutect2, varscan2
- CNST | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776494504, COSV63621582; called by muse, mutect2, varscan2
- CYP1A2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs761941661, COSV59659344; called by muse, mutect2, varscan2
- FUBP1 | c.996T>A p.C332* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV53928136; called by muse, mutect2, varscan2
- LAMA2 | c.8330C>T p.A2777V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV70342762; called by muse, mutect2, varscan2
- PRSS54 | c.198C>A p.H66Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54689276; called by muse, mutect2, varscan2
- SRD5A1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as rs200332603; called by muse, mutect2, varscan2
- TFAP2B | c.1034C>A p.T345K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.264); catalogued as rs770612426, COSV53825963; called by muse, mutect2, varscan2
- USP31 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs776883130, COSV54850565; called by muse, mutect2
- CAMK2D | c.735C>T p.A245= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV56427787; called by muse, mutect2, varscan2
- DHX35 | c.1104C>T p.Y368= | Silent (SNP) | VAF 66/329 reads (20%) | catalogued as rs1431798305, COSV52668745; called by mutect2, varscan2
- FOXM1 | c.1881G>A p.T627= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs374998139; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZBED9 | c.2997C>T p.C999= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs1270363147, COSV71729252; called by muse, mutect2, varscan2
